Somatic mutation profile of tumor specimen TCGA-EM-A2CL-01A (aliquot TCGA-EM-A2CL-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.9 years (11,649 days).
Specimen TCGA-EM-A2CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 130e7ca1-679a-469f-bc9e-f7cabf5a72ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CL-10A (Blood Derived Normal), aliquot TCGA-EM-A2CL-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccc5f30e-de78-4487-9733-8215ac181fa9

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 68/84 reads (81%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV63309272; called by muse, mutect2, varscan2
- AGL | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV54056820; called by muse, mutect2, varscan2
- GABRR2 | c.1135G>C p.G379R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV68765971; called by muse, mutect2, varscan2
- LRRIQ3 | c.1805A>G p.D602G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV63048440; called by muse, mutect2, varscan2
- MPO | c.1635del p.I546Sfs*12 | Frame Shift Del (DEL) | VAF 81/216 reads (38%) | called by mutect2, pindel, varscan2
- OR2L13 | c.357C>T p.Y119= | Silent (SNP) | VAF 38/213 reads (18%) | catalogued as rs1438157332, COSV63553802; called by muse, mutect2, varscan2
